Somatic mutation profile of tumor specimen 0E1KOK from CCDI case PBCVSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1KOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 389ada8f-5a86-46b5-b42d-77cc480c094c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KO1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad60fab-a29f-446c-8e6e-4b8dc56ed068

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPFIBP2 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 290/486 reads (60%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.51); catalogued as COSV55080525; called by muse, mutect2, varscan2
- CCDC89 | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 24/649 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- GRM8 | c.2653C>A p.L885I | Missense Mutation (SNP) | VAF 24/706 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- TPRX1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 123/197 reads (62%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATAD3A | c.747G>A p.R249= | Silent (SNP) | VAF 360/585 reads (62%) | called by muse, mutect2, varscan2
- GTPBP1 | c.1110C>T p.G370= | Silent (SNP) | VAF 75/336 reads (22%) | catalogued as rs141693189; called by muse, mutect2, varscan2
